Somatic mutation profile of tumor specimen C3N-03765-07 (aliquot CPT0247190006) from CPTAC case C3N-03765, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 60.9 years (22,260 days).
Specimen C3N-03765-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f82538f2-b123-4e8e-adc8-824df1083284.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03765-31 (Blood Derived Normal), aliquot CPT0247230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/714678b1-bd42-4bdd-adff-a45c99f4fbba

The open-access MAF lists 293 somatic variants for this specimen: 199 protein-altering or splice-affecting, 59 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 59, Intron 14, Nonsense Mutation 13, Splice Site 9, RNA 9, Frame Shift Del 6, 3'UTR 6, 5'UTR 4, Frame Shift Ins 3, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 71/292 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- WWOX | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 64/412 reads (16%) | catalogued as rs886039653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC092442.1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 24/318 reads (8%) | catalogued as COSV51525720; called by muse, mutect2
- ADAMTS20 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs778375054; called by muse, mutect2, varscan2
- AHNAK | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV99946074; called by muse, mutect2, varscan2
- ANAPC2 | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.647); catalogued as rs1171160272; called by muse, mutect2, varscan2
- ARSF | c.1635C>G p.I545M | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100839630; called by muse, mutect2
- B9D1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52069317; called by muse, mutect2
- BARHL1 | c.335C>A p.A112E | Missense Mutation (SNP) | VAF 81/595 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs986962758; called by muse, mutect2, varscan2
- BTBD10 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.492); catalogued as rs760524210, COSV53401544; called by muse, mutect2, varscan2
- CACNA1A | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577006493, COSV100802322; called by muse, varscan2
- CAPS2 | c.1221A>C p.K407N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1195440885; called by muse, mutect2, varscan2
- CCDC102B | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV60137131; called by muse, mutect2
- CDH23 | c.5788G>A p.D1930N | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as CM082533; called by muse, mutect2, varscan2
- CHAT | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.624); catalogued as rs1418885156; called by muse, mutect2
- CNTNAP2 | c.1498+2T>A p.X500_splice | Splice Site (SNP) | VAF 30/310 reads (10%) | catalogued as rs770435238; called by muse, mutect2
- COL24A1 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV100993159; called by muse, mutect2
- COLEC12 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV68371846; called by muse, mutect2
- CSHL1 | c.293C>T p.T98M (on ENST00000309894 / NM_022581.3; = p.T4M on NM_001318.4) | Missense Mutation (SNP) | VAF 34/550 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs149910727, COSV51987106; called by muse, mutect2
- CSMD1 | c.6841G>T p.D2281Y (on ENST00000520002; = p.D2280Y on NM_033225.6) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59288692, COSV59383511; called by muse, mutect2
- CYP24A1 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV53772690, COSV53774957; called by muse, mutect2, varscan2
- DAGLA | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); catalogued as COSV57197159; called by muse, mutect2
- DARS2 | c.128-1G>T p.X43_splice | Splice Site (SNP) | VAF 30/374 reads (8%) | catalogued as rs267598175; called by muse, mutect2
- DDX58 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 11/343 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); catalogued as rs1413305842; called by muse, mutect2
- DPF2 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52888447, COSV52891275; called by muse, mutect2, varscan2
- ELMOD1 | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV56190750; called by muse, mutect2, varscan2
- FMOD | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271438685, COSV100724565; called by muse, mutect2, varscan2
- GALNT12 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs771338633; called by muse, mutect2
- GATA1 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as rs782474159, COSV64962054, COSV64963000; called by muse, mutect2, varscan2
- GRM6 | c.1397C>A p.A466E | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51443174; called by muse, mutect2, varscan2
- HS6ST3 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747297518, COSV65017001; called by muse, mutect2, varscan2
- IL23A | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57336577; called by muse, mutect2, varscan2
- JAK1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1240783724, COSV61097942; called by muse, mutect2
- KANSL2 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 39/518 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs1371872823; called by muse, mutect2
- KIAA1841 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54376216; called by muse, mutect2
- LRRIQ1 | c.3725G>T p.S1242I | Missense Mutation (SNP) | VAF 134/618 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV67828948; called by muse, mutect2, varscan2
- MAN2B2 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1435636529; called by muse, mutect2, varscan2
- MED13 | c.15C>G p.F5L | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs888761387; called by muse, mutect2
- MICU3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs565232734, COSV58846122; called by muse, mutect2, varscan2
- MIEF1 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs752098023, COSV57478069; called by muse, mutect2
- NEFL | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 60/657 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as rs1249514180, COSV99647917; ClinVar: uncertain significance; called by muse, mutect2
- NETO1 | c.868+1G>A p.X290_splice | Splice Site (SNP) | VAF 36/221 reads (16%) | catalogued as COSV55015227; called by muse, mutect2
- NLRP7 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 71/524 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60179801; called by muse, mutect2, varscan2
- NUDT13 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100624857; called by muse, mutect2
- OLFML1 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV55080877; called by muse, mutect2
- OR4C6 | c.748G>T p.V250F | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.208); catalogued as rs75211559; called by muse, mutect2, varscan2
- OR4S1 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481463940; called by muse, mutect2, varscan2
- OR51T1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs201004265; called by muse, mutect2
- OR5H2 | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs771035636; called by muse, mutect2
- PC | c.752-2A>G p.X251_splice | Splice Site (SNP) | VAF 43/326 reads (13%) | catalogued as rs111606137; called by muse, mutect2, varscan2
- PHKA1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147219387; called by muse, mutect2, varscan2
- POU5F1B | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 32/450 reads (7%) | catalogued as rs769533326; called by muse, mutect2
- RTN4RL1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 42/308 reads (14%) | catalogued as COSV58677550; called by muse, mutect2, varscan2
- RUNX1T1 | c.581G>T p.R194L (on ENST00000265814 / NM_001198628.1; = p.R167L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV56138052; called by muse, mutect2, varscan2
- SCCPDH | c.1004C>G p.S335* | Nonsense Mutation (SNP) | VAF 7/164 reads (4%) | catalogued as COSV63618545; called by muse, mutect2
- SEMA6D | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100317674; called by muse, mutect2
- SLC35A5 | c.1074A>T p.E358D | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1324901030; called by muse, mutect2
- SLITRK6 | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.941); catalogued as COSV68391210; called by muse, mutect2
- SPAM1 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772738728, COSV56145566; called by muse, mutect2
- TMEM131 | c.3205A>G p.T1069A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51787629; called by muse, mutect2, varscan2
- TRAK2 | c.2227A>G p.K743E | Missense Mutation (SNP) | VAF 28/439 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs1171443795; called by muse, mutect2
- ZNF322 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 27/434 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV70652306; called by muse, mutect2
- ZNF441 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100777457; called by muse, mutect2, varscan2
- ZNF454 | c.205del p.R69Gfs*18 | Frame Shift Del (DEL) | VAF 19/153 reads (12%) | catalogued as rs1217832391; called by mutect2, pindel, varscan2
- ABCA13 | c.11162A>T p.Q3721L | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC3 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACVR2A | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- AKAP9 | c.9820G>C p.E3274Q (on ENST00000359028; = p.E3250Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGEF25 | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 102/467 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ASIC2 | c.707-1G>A p.X236_splice | Splice Site (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- ATP4A | c.1016T>A p.V339E | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- BASP1 | c.580A>G p.S194G | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- BLOC1S5 | c.84_99del p.A29Sfs*28 | Frame Shift Del (DEL) | VAF 34/183 reads (19%) | called by mutect2, pindel
- C11orf54 | c.939del p.R314Efs*18 (on ENST00000331239; = p.R264Efs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- C1orf94 | c.1777_1778insT p.G593Vfs*17 (on ENST00000488417 / NM_001134734.2; = p.G403Vfs*17 on NM_032884.5) | Frame Shift Ins (INS) | VAF 22/154 reads (14%) | called by mutect2, pindel, varscan2
- CARD11 | c.2027T>G p.L676R | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC88A | c.5261dup p.L1754Ffs*9 (on ENST00000436346 / NM_001365480.1; = p.L1726Ffs*9 on NM_018084.5) | Frame Shift Ins (INS) | VAF 30/239 reads (13%) | called by mutect2, pindel, varscan2
- CDCA2 | c.1424C>G p.S475* | Nonsense Mutation (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- CENPE | c.5647G>C p.E1883Q | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2
- CLDN17 | c.218T>A p.L73H | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNNM1 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.082); called by muse, mutect2
- CNOT1 | c.2000C>G p.S667* | Nonsense Mutation (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- COG4 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPED1 | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 84/526 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CPNE4 | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.2); called by muse, mutect2
- CRACDL | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 28/221 reads (13%) | called by muse, mutect2, varscan2
- CROCC2 | c.2139G>C p.E713D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CRYZ | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CUBN | c.6319A>T p.K2107* | Nonsense Mutation (SNP) | VAF 80/330 reads (24%) | called by muse, mutect2, varscan2
- CUL3 | c.1842+2T>C p.X614_splice | Splice Site (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2
- CWC22 | c.807A>T p.A269= | Splice Region (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- EBNA1BP2 | c.808A>C p.S270R | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ELFN1 | c.1877G>T p.R626L | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- FAH | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM47C | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FGFR3 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 96/426 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FHOD3 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FRAS1 | c.6583G>C p.E2195Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by mutect2, varscan2
- FYN | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- GARNL3 | c.1492T>G p.W498G | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAS1 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2
- GHR | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 51/439 reads (12%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 84/457 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- GJD2 | c.708C>A p.C236* | Nonsense Mutation (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- GUCD1 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2
- HERC2 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HMGCR | c.1693A>T p.S565C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMMR | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- HSPA8 | c.1569G>C p.E523D | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2
- IDH1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 52/410 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFT140 | c.2063C>G p.P688R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- IGHM | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); called by muse, varscan2
- IPO7 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IRX5 | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMJD4 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- KALRN | c.3745G>C p.E1249Q | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNN2 | c.397C>T p.R133W (on ENST00000264773; = p.R345W on NM_021614.4) | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNN2 | c.995G>C p.C332S (on ENST00000264773; = p.C544S on NM_021614.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KCNT2 | c.2257G>C p.V753L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KDM3B | c.1011G>C p.Q337H | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- KIAA1549 | c.5660C>T p.S1887L (on ENST00000422774 / NM_001164665.2; = p.S1871L on NM_020910.3) | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- KIFC3 | c.1634_1645del p.P545_N548del | In Frame Del (DEL) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- KLHL40 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDB3 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- MAP1A | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 35/222 reads (16%) | called by muse, mutect2, varscan2
- MAST2 | c.4000C>G p.R1334G | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAZ | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- MRPS7 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 33/577 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2
- MUC16 | c.4596A>T p.L1532F | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MYEOV | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NEFL | c.925C>A p.R309S | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NF1 | c.6704+1del | Frame Shift Del (DEL) | VAF 40/301 reads (13%) | called by mutect2, pindel, varscan2
- NR1H4 | c.262G>A p.E88K (on ENST00000551379 / NM_001206993.2; = p.E78K on NM_005123.4) | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.4); called by muse, mutect2
- NT5DC4 | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- NUFIP1 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OMD | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ONECUT2 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 15/180 reads (8%) | called by muse, mutect2
- OR10T2 | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- OR2Y1 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- OR5I1 | c.415T>C p.S139P | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR5M1 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- OR5R1 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OTOF | c.1690T>C p.S564P | Missense Mutation (SNP) | VAF 51/712 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- PARP15 | c.1645G>T p.D549Y (on ENST00000464300 / NM_001113523.3; = p.D315Y on NM_152615.2) | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- PCDH11X | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PCDH8 | c.3041T>A p.L1014Q | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PCDHB2 | c.243G>T p.R81S | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.006); called by muse, mutect2
- PCDHGA4 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PDE11A | c.1367+1G>T p.X456_splice | Splice Site (SNP) | VAF 55/375 reads (15%) | called by muse, mutect2, varscan2
- PIGK | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- PITPNM1 | c.234del p.K79Rfs*6 | Frame Shift Del (DEL) | VAF 76/581 reads (13%) | called by mutect2, pindel, varscan2
- PIWIL2 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- PLCB4 | c.3140G>T p.C1047F | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLRG1 | c.1461A>C p.K487N | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PNMA8B | c.1485G>C p.E495D | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.761); called by muse, mutect2
- PRPF40A | c.225T>G p.S75R | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PSMD3 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 100/563 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAD50 | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- RMDN3 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- RNF17 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ROBO2 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.395); called by muse, mutect2
- RPAP1 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RTL1 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RXFP2 | c.1269G>C p.W423C | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SAGE1 | c.471C>G p.H157Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SAMD9 | c.2302G>T p.V768L | Missense Mutation (SNP) | VAF 62/586 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN5A | c.2478C>A p.N826K | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SESTD1 | c.887T>G p.L296R | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SH2B2 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2
- SIGLEC6 | c.69G>C p.G23= | Splice Region (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- SLC22A12 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SLC22A12 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC35A5 | c.104_120del p.L35Cfs*3 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel
- SLC6A8 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A1 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 37/527 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2
- SMO | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SMPD3 | c.694dup p.D232Gfs*26 | Frame Shift Ins (INS) | VAF 27/256 reads (11%) | called by mutect2, pindel, varscan2
- SP140L | c.1443G>C p.L481F | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA31A1 | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 80/1032 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.025); called by muse, mutect2
- SRSF2 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 43/225 reads (19%) | called by muse, mutect2, varscan2
- ST18 | c.87-2A>G p.X29_splice | Splice Site (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- TENM2 | c.2179C>T p.P727S (on ENST00000518659 / NM_001122679.2; = p.P495S on NM_001080428.3) | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TFEB | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- TMC5 | c.1832A>T p.Q611L (on ENST00000396229 / NM_001105248.1; = p.Q365L on NM_024780.5) | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2
- TMTC1 | c.848G>T p.G283V (on ENST00000539277 / NM_001193451.2; = p.G175V on NM_175861.3) | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRBV19 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TRHR | c.736A>T p.N246Y | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TRIOBP | c.956C>G p.T319S | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS33A | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by mutect2, varscan2
- ZFHX3 | c.5875C>A p.Q1959K | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF416 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); called by muse, mutect2
- ZNF480 | c.1003A>G p.R335G | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF594 | c.1732C>A p.Q578K | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF628 | c.3166G>C p.V1056L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ZNF649 | c.1377T>A p.D459E | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- ZNF677 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZNF718 | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZP4 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRG4 | c.6630A>T p.S2210= | Silent (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- AL358113.1 | c.3348G>T p.P1116= | Silent (SNP) | VAF 91/486 reads (19%) | called by muse, mutect2, varscan2
- ANKRD34A | c.897C>G p.P299= | Silent (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- ARMC9 | c.576G>A p.T192= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs750261615, COSV63020309; called by mutect2, varscan2
- ASAP2 | c.93G>C p.A31= | Silent (SNP) | VAF 58/349 reads (17%) | catalogued as rs778938210, COSV55637029; called by muse, mutect2, varscan2
- ATP6V1B2 | c.771C>G p.V257= | Silent (SNP) | VAF 12/273 reads (4%) | called by muse, mutect2
- C1orf127 | c.2169A>T p.S723= | Silent (SNP) | VAF 17/276 reads (6%) | called by muse, mutect2
- CBFA2T3 | c.1623C>T p.D541= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs767267455; called by muse, mutect2, varscan2
- CHD4 | c.3171C>T p.L1057= (on ENST00000357008 / NM_001363606.2; = p.L1070= on NM_001273.5) | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- CHRNB2 | c.1257G>T p.P419= | Silent (SNP) | VAF 87/358 reads (24%) | catalogued as rs199743038; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNOT4 | c.849C>T p.L283= (on ENST00000315544 / NM_001190848.1; = p.L280= on NM_013316.4) | Silent (SNP) | VAF 21/308 reads (7%) | called by muse, mutect2
- COL25A1 | c.114G>T p.A38= | Silent (SNP) | VAF 19/256 reads (7%) | catalogued as COSV101211347; called by muse, mutect2
- CROCC2 | c.1920G>C p.L640= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- CSMD2 | c.4716C>T p.S1572= | Silent (SNP) | VAF 50/252 reads (20%) | catalogued as rs138922446; called by muse, mutect2, varscan2
- CSNK1G2 | c.810C>T p.T270= | Silent (SNP) | VAF 68/255 reads (27%) | called by muse, varscan2
- CTCFL | c.693T>G p.P231= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as rs1168045107; called by muse, varscan2
- CTNNA2 | c.423G>T p.A141= | Silent (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- DYSF | c.696G>T p.L232= | Silent (SNP) | VAF 10/233 reads (4%) | catalogued as rs1399451547; called by muse, mutect2
- ETFB | c.582G>T p.T194= | Silent (SNP) | VAF 42/270 reads (16%) | called by muse, mutect2, varscan2
- FOXRED1 | c.1311C>T p.F437= | Silent (SNP) | VAF 31/314 reads (10%) | called by muse, mutect2
- GALNT18 | c.1761G>T p.V587= | Silent (SNP) | VAF 37/240 reads (15%) | called by mutect2, varscan2
- GHR | c.1353A>T p.A451= | Silent (SNP) | VAF 52/446 reads (12%) | called by muse, mutect2, varscan2
- HCFC1R1 | c.351G>A p.L117= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- IMPG2 | c.612G>A p.E204= | Silent (SNP) | VAF 37/333 reads (11%) | called by muse, mutect2, varscan2
- IRX5 | c.1254C>T p.F418= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs373826345, COSV58059892; called by muse, mutect2, varscan2
- KCNN2 | c.1566C>T p.H522= (on ENST00000264773; = p.H734= on NM_021614.4) | Silent (SNP) | VAF 37/480 reads (8%) | catalogued as rs370602863; called by muse, mutect2
- KCNT1 | c.2424C>T p.S808= (on ENST00000488444; = p.S827= on NM_020822.3) | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- KRTDAP | c.54C>T p.H18= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs770669430; called by muse, mutect2, varscan2
- LRCH3 | c.39C>T p.A13= | Silent (SNP) | VAF 128/451 reads (28%) | catalogued as rs753964576; called by muse, mutect2, varscan2
- LRGUK | c.27G>A p.L9= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as rs1301077843, COSV53642611; called by muse, mutect2
- LRP6 | c.3012G>C p.V1004= | Silent (SNP) | VAF 26/440 reads (6%) | called by muse, mutect2
- LRPPRC | c.3105C>T p.F1035= | Silent (SNP) | VAF 48/310 reads (15%) | catalogued as COSV99581401; called by muse, mutect2, varscan2
- LRRIQ1 | c.1032G>A p.R344= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs781069563, COSV101279256; called by muse, mutect2, varscan2
- LTBP1 | c.1995T>C p.C665= (on ENST00000404816 / NM_206943.4; = p.C339= on NM_000627.4) | Silent (SNP) | VAF 33/217 reads (15%) | catalogued as rs564087838; called by muse, mutect2, varscan2
- MACF1 | c.11073G>C p.L3691= (on ENST00000372915; = p.L1624= on NM_012090.5) | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- MED11 | c.294C>T p.D98= | Silent (SNP) | VAF 26/221 reads (12%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.276T>C p.H92= | Silent (SNP) | VAF 40/364 reads (11%) | catalogued as rs1430648111; called by muse, mutect2, varscan2
- NF1 | c.1422C>T p.S474= | Silent (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- NOS1 | c.376C>T p.L126= | Silent (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- OR11L1 | c.276C>T p.I92= | Silent (SNP) | VAF 105/489 reads (21%) | called by muse, mutect2, varscan2
- OR2M2 | c.18G>A p.Q6= | Silent (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- OVCH1 | c.591C>A p.P197= | Silent (SNP) | VAF 61/319 reads (19%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1263T>C p.Y421= | Silent (SNP) | VAF 65/722 reads (9%) | called by muse, mutect2
- PDS5A | c.1701G>A p.E567= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- PLXDC2 | c.243C>T p.S81= | Silent (SNP) | VAF 17/475 reads (4%) | catalogued as rs1171229004; called by muse, mutect2
- RBMXL3 | c.2565T>C p.Y855= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs1216099235; called by muse, mutect2, varscan2
- SCP2D1 | c.222C>A p.I74= | Silent (SNP) | VAF 62/425 reads (15%) | called by muse, mutect2, varscan2
- SLC9A3 | c.2394C>T p.F798= | Silent (SNP) | VAF 34/448 reads (8%) | called by muse, mutect2
- STYXL2 | c.3346C>A p.R1116= | Silent (SNP) | VAF 83/441 reads (19%) | called by muse, mutect2, varscan2
- SWSAP1 | c.93G>A p.G31= (on ENST00000312423; = p.G52= on NM_175871.4) | Silent (SNP) | VAF 35/354 reads (10%) | catalogued as rs1568326688; called by muse, mutect2
- TANGO6 | c.1599C>T p.L533= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- TMCC2 | c.690G>T p.L230= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- TPTE | c.1005G>A p.A335= (on ENST00000618007 / NM_199261.4; = p.A317= on NM_199259.4) | Silent (SNP) | VAF 28/310 reads (9%) | catalogued as rs755583335; called by muse, mutect2
- TRPC7 | c.37C>A p.R13= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs577536758; called by muse, mutect2, varscan2
- USP10 | c.2076G>A p.E692= | Silent (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- VCAN | c.78G>T p.V26= | Silent (SNP) | VAF 35/259 reads (14%) | catalogued as COSV99426909; called by muse, mutect2, varscan2
- VIT | c.1830G>A p.R610= (on ENST00000389975 / NM_001177969.1; = p.R625= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- XIAP | c.804G>T p.R268= | Silent (SNP) | VAF 65/226 reads (29%) | called by muse, mutect2, varscan2
- ZNF536 | c.2643C>T p.P881= | Silent (SNP) | VAF 29/172 reads (17%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27196782 C>A | 3'Flank (SNP) | VAF 126/595 reads (21%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.679C>A | RNA (SNP) | VAF 43/307 reads (14%) | called by muse, mutect2, varscan2
- AP1S3 | c.430-5810A>T | Intron (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP27P2 | n.394C>G | RNA (SNP) | VAF 19/355 reads (5%) | called by muse, mutect2
- CABYR | c.*17-232T>G | Intron (SNP) | VAF 37/434 reads (9%) | called by muse, mutect2
- CHRNA4 | c.274-40C>A | Intron (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.5133G>A | RNA (SNP) | VAF 9/184 reads (5%) | catalogued as COSV61776940; called by muse, mutect2
- FAM215A | n.179C>A | RNA (SNP) | VAF 34/178 reads (19%) | called by muse, varscan2
- FAS | c.*835_*837del | 3'UTR (DEL) | VAF 17/121 reads (14%) | catalogued as rs1461336499; called by pindel, varscan2
- H2BP2 | n.1062-464A>T | Intron (SNP) | VAF 65/393 reads (17%) | called by muse, mutect2, varscan2
- HEG1 | c.1589-937C>T | Intron (SNP) | VAF 10/116 reads (9%) | catalogued as rs141260685; called by muse, mutect2
- KDM5C | c.*273G>T | 3'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- LINC02870 | n.498G>T | RNA (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- MIR651 | n.18dup | RNA (INS) | VAF 20/64 reads (31%) | catalogued as rs776510180; called by mutect2, pindel, varscan2
- MRPS23 | c.44+10C>T | Intron (SNP) | VAF 18/251 reads (7%) | catalogued as rs906095658; called by muse, mutect2
- NDUFA10 | c.670-14C>A | Intron (SNP) | VAF 37/410 reads (9%) | called by muse, mutect2
- OBSCN | c.18662-1958C>T | Intron (SNP) | VAF 10/110 reads (9%) | catalogued as rs376200518; called by muse, mutect2
- PAGE3 | c.*11G>C | 3'UTR (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- PCP4L1 | c.-24C>T | 5'UTR (SNP) | VAF 41/527 reads (8%) | catalogued as rs1256006442; called by muse, mutect2
- PRKCZ | c.975-92G>T | Intron (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- PRPH | c.607-33C>T | Intron (SNP) | VAF 69/513 reads (13%) | called by muse, mutect2, varscan2
- RNF5P1 | n.455G>T | RNA (SNP) | VAF 73/390 reads (19%) | called by muse, mutect2, varscan2
- SCN4B | c.*1399C>T | 3'UTR (SNP) | VAF 48/720 reads (7%) | called by muse, mutect2
- SHOX | c.-47C>G | 5'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2
- SIVA1 | c.-7C>G | 5'UTR (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- SMC1A | c.2196+67G>T | Intron (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- SNORD115-21 | n.77G>A | RNA (SNP) | VAF 49/588 reads (8%) | called by muse, mutect2
- SPATA31C2 | n.2946G>A | RNA (SNP) | VAF 60/710 reads (8%) | called by muse, mutect2
- TEF | c.157+740T>C | Intron (SNP) | VAF 36/478 reads (8%) | catalogued as rs745514168; called by muse, mutect2
- TLR9 | c.-19G>A | 5'UTR (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.305-287C>T | Intron (SNP) | VAF 32/350 reads (9%) | catalogued as rs552631498; called by muse, mutect2
- TRMT9B | chr8:13031200 T>G | 3'Flank (SNP) | VAF 42/259 reads (16%) | called by muse, mutect2, varscan2
- TUBA4A | c.4-589C>T | Intron (SNP) | VAF 14/136 reads (10%) | catalogued as COSV50281400; called by muse, mutect2
- UMPS | c.*1167A>T | 3'UTR (SNP) | VAF 79/222 reads (36%) | called by muse, mutect2, varscan2
- YLPM1 | c.*129A>T | 3'UTR (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
